Gene-level copy-number profile of tumor specimen TCGA-23-1110-01A from TCGA case TCGA-23-1110, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.1 years (15,383 days).
Specimen TCGA-23-1110-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.fd1d363e-fef7-4b4e-b8cf-581dac29eafe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1110-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cd43ad7e-1fd8-4861-9556-5cba10da9dbf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,045; copy number 2: 18,234; copy number 3: 23,543; copy number 4: 9,132; copy number 5: 5,593; copy number 6: 488; copy number 7: 717; copy number 8: 1,042; copy number 10: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1110-01A-01D-0428-01): tumor purity 0.97, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:85,036,314–85,264,457, 1 gene (within-gene range 0–1): LRRIQ1.
- chr17:69,577,251–69,903,000, 2 genes (within-gene range 0–3): LINC01483, AC002545.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,774 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:19,143,695–23,031,780, 43 genes, copy number 7 (within-gene range 5–7): AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1.
- chr6:101,181,257–122,211,811, 293 genes, copy number 7–8 (broad region; genes not listed).
- chr9:14,475–16,410,990, 213 genes, copy number 8 (broad region; genes not listed).
- chr9:16,473,188–16,476,237, 1 gene, copy number 8: AL449983.1.
- chr10:44,712–1,289,426, 23 genes, copy number 7–10: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200.
- chr10:1,201,406–1,293,002, 2 genes, copy number 7: AL392083.2, AL392083.1.
- chr10:4,201,141–4,243,912, 1 gene, copy number 7: LINC00702.
- chr11:24,496,970–26,047,598, 8 genes, copy number 7–10 (within-gene range 2–10): LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1.
- chr13:69,700,594–91,354,579, 218 genes, copy number 7 (broad region; genes not listed).
- chr13:91,485,793–91,486,870, 1 gene, copy number 7: AL356118.1.
- chr17:74,599,840–77,680,687, 163 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr20:33,161,768–64,313,132, 808 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,045. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
